Somatic mutation profile of tumor specimen TCGA-Q1-A73R-01A (aliquot TCGA-Q1-A73R-01A-11D-A33O-09) from TCGA case TCGA-Q1-A73R, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 45.7 years (16,701 days).
Specimen TCGA-Q1-A73R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db877bb6-383a-4544-91a7-ca1eea9f8923.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A73R-10B (Blood Derived Normal), aliquot TCGA-Q1-A73R-10B-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc8d3257-e4bb-4db1-ad3a-6d9b85e993b4

The open-access MAF lists 46 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Frame Shift Ins 3, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934dup p.G646Wfs*12 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | hotspot (GDC flag); catalogued as rs750318549, COSV60102510; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 34/69 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF17 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs781760252, COSV55232161, COSV99735331; called by muse, mutect2, varscan2
- CDH11 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs1459302268, COSV51760377; called by muse, mutect2, varscan2
- CXCR5 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as rs1565607015, COSV52684039; called by muse, mutect2, varscan2
- ENPEP | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs767349194, COSV54450380; called by muse, mutect2, varscan2
- G6PD | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs782372471, COSV63703068; called by muse, mutect2, varscan2
- GNE | c.1607C>T p.S536F (on ENST00000396594 / NM_001128227.3; = p.S505F on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV64951776; called by muse, mutect2, varscan2
- KDF1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV57670755, COSV57671293; called by muse, mutect2, varscan2
- KIF26B | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1203953962, COSV63640652; called by muse, mutect2, varscan2
- LINGO2 | c.797T>A p.F266Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1159523408, COSV58059426; called by muse, mutect2, varscan2
- LMAN1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | catalogued as rs951475866, CM990809, COSV51826707; called by muse, mutect2, varscan2
- MSH4 | c.695T>C p.F232S | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54202101; called by muse, mutect2, varscan2
- MXI1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as rs770403856, COSV53291273; called by muse, mutect2, varscan2
- NAA15 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56719401; called by muse, mutect2, varscan2
- NBN | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619003; called by muse, mutect2
- NKRF | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV58661439; called by muse, mutect2, varscan2
- NUP85 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55463922; called by muse, mutect2, varscan2
- NWD1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764495804, COSV60341670; called by muse, mutect2, varscan2
- OVCH1 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55480397; called by muse, mutect2, varscan2
- PARP16 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV56035235, COSV56036600; called by muse, mutect2, varscan2
- PCDHB13 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782296190, COSV53396206; called by muse, mutect2, varscan2
- PCDHGB3 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs753032334, COSV53938709; called by mutect2, varscan2
- PSG6 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51832658; called by muse, mutect2, varscan2
- RAB5A | c.438+1G>A p.X146_splice | Splice Site (SNP) | VAF 23/64 reads (36%) | catalogued as COSV56084398; called by muse, mutect2, varscan2
- RPS6KA3 | c.1859A>T p.N620I | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV65387700; called by muse, mutect2, varscan2
- SPRR2D | c.95G>C p.C32S | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV64209174; called by muse, mutect2, varscan2
- TAS2R19 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV66828345; called by muse, mutect2, varscan2
- TCHHL1 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs984285030, COSV64285632; called by muse, mutect2, varscan2
- TTN | c.24114G>A p.A8038= (on ENST00000591111; = p.A7111= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as rs397517514, COSV60024067; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE2O | c.1937C>A p.A646D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.767); catalogued as COSV100084338, COSV60062700; called by muse, mutect2, varscan2
- UCHL1 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV99449073; called by muse, mutect2
- VWF | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139579968; called by muse, mutect2, varscan2
- WWC2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs780813875, COSV66713437; called by muse, mutect2, varscan2
- ZBTB12 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs756745454, COSV100976934, COSV64993795; called by muse, mutect2, varscan2
- ARID3B | c.1537dup p.Q513Pfs*69 (on ENST00000622429 / NM_001307939.1; = p.Q512Pfs*69 on NM_006465.4) | Frame Shift Ins (INS) | VAF 17/41 reads (41%) | called by pindel, varscan2
- TP73 | c.674_677dup p.D227Cfs*3 | Frame Shift Ins (INS) | VAF 33/37 reads (89%) | called by mutect2, pindel, varscan2
- BCOR | c.2871G>A p.P957= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs773560546, COSV60706193; called by muse, mutect2, varscan2
- BCOR | c.1434C>T p.S478= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs371048617, COSV60706207; called by muse, mutect2, varscan2
- EAPP | c.390G>A p.K130= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV51651757; called by muse, mutect2, varscan2
- GPRC5A | c.1023C>T p.H341= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs147094157; called by muse, varscan2
- ILK | c.1236C>T p.T412= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs569395635, COSV54990435; called by muse, mutect2, varscan2
- KMT2D | c.11715G>A p.Q3905= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV56435543; called by muse, varscan2
- SLC9B2 | c.108G>A p.K36= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1253160859, COSV60018965; called by muse, mutect2, varscan2
- TG | c.8139C>T p.A2713= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs768913752, COSV99600356; called by muse, mutect2, varscan2
- RPSA | c.134-157G>A | Intron (SNP) | VAF 38/85 reads (45%) | catalogued as rs749408758, COSV57191412; called by muse, mutect2, varscan2
